Surgical pathology report (de-identified scan), TCGA case TCGA-IQ-A61O, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-IQ-A61O-01A (Primary Tumor).

[page 1 of 12]
13

AGE/SEX: /M
REG DR:

Received:
Copies to:

Collected:

SPECIMEN ID:

- A. SOFT TISSUE - TISSUE MEDIAL TO MANDIBLE FS, B. SOFT TISSUE - TISSUE TOOTH SOCKET FS,
C. MASSETER MUSCLE - MASSETER MUSCLE INFERIOR FS,
D. MASSETER MUSCLE - MASSETER SUPERIOR CLIP INFERIOR,
E. SOFT TISSUE - TISSUE OVER LATERAL MANDIBLE ANTERIOR FS,
F. SOFT TISSUE - TISSUE OVER LATERAL MANDIBLE POSTERIOR FS,
G. BONE - FINAL BONE MARGIN ANTERIOR FS, H. BUCCAL MUCOSA, NOS - BUCCAL MUCOSA FS,
I. FLOOR OF MOUTH, NOS - FLOOR OF MOUTH MUSCLE CLIP ANTERIOR FS,
J. PALATE, NOS - MARGINAL PALATE CLIP ANTERIOR FS,
K. JAW, NOS - ALVEOLAR RIDGE INFERIOR FS,
L. OROPHARYNX - ORAL PHARYNGEAL MARGIN CLIP INFERIOR FS, M. PERINEURIUM - PERINEURIUM FS,
N. JAW, NOS - DEEP SUPERIOR ALVEOLAR RIDGE FS, O. JAW, NOS - SUPERIOR ALVEOLAR RIDGE FS,
P. SOFT TISSUE - COMPOSITE RESECTION RIGHT RETROMOLAR TRIGONE STITCH SUPERIOR,
Q. CONNECTIVE TISSUE, NOS - PERIOSTEUM MEDIAL MANDIBLE,
R. LYMPH NODE - LEVEL 1 SENTINEL NODE RIGHT PERIFACIAL ANTERIOR FS,
S. LYMPH NODE - SENTINEL NODE #2, T. LYMPH NODE - LYMPH NODE JUGULAR VEIN,
U. LYMPH NODE - LEVEL 2 SENTINEL NODE, V. LYMPH NODE - SECOND LEVEL 2 SENTINEL NODE,
W. MUSCLE - PTERYGOID MUSCLE MARGIN POSTERIOR,
X. MUSCLE - PTERYGOID MUSCLE MARGIN ANTERIOR, Y. TOOTH - TOOTH #31,
Z. MAXILLA, NOS - FINAL MARGIN AT MAXILLA, AA. BONE - FINAL BONE INFERIOR,
BB. MANDIBLE, NOS - FINAL MARGIN AT MANDIBLE,
CC. MANDIBLE, NOS - MARGINAL SECTIONAL MANDIBULECTOMY,
DD. SOFT TISSUE - TISSUE ABOVE MANDIBULAR MARGIN,
EE. LYMPH NODE - LYMPH NODE ADJACENT TO TAIL OF PAROTID,
FF. LYMPH NODE - RIGHT NECK LEVEL 1A, GG. LYMPH NODE - LEVEL 5 NODE,
HH. LYMPH NODE - RIGHT NECK LEVELS 1B, 2A, 3, 4, II. LYMPH NODE - RIGHT NECK LEVEL 2B

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

ICD-0-3
Carcinoma, squamous cell, spindle cell
8074/3
Site ^{path} Oropharynx NOS C10.9
Cell Bone & Tongue NOS C01.9
JW 5/14/13

[page 2 of 12]
(Continued)

*** FINAL DIAGNOSIS **

A. TISSUE MEDIAL TO MANDIBLE:

Skeletal muscle, negative for carcinoma.

B. TISSUE TOOTH SOCKET:

Fibrous and bone tissue, negative for carcinoma.

C. MASSETER MUSCLE INFERIOR:

Skeletal muscle, negative for carcinoma.

D. MASSETER SUPERIOR:

Skeletal muscle, negative for carcinoma.

E. TISSUE OVER LATERAL MANDIBLE ANTERIOR:

Skeletal muscle, negative for carcinoma.

F. TISSUE OVER LATERAL MANDIBLE POSTERIOR:

Skeletal muscle, negative for carcinoma.

G. FINAL BONE MARGIN ANTERIOR:

Fibrous and bone tissue, negative for carcinoma.

H. BUCCAL MUCOSA:

Squamous mucosa, submucosa, salivary gland and skeletal muscle, negative for carcinoma.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 3 of 12]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

I. FLOOR OF MOUTH MUSCLE:

Squamous mucosa and submucosa; negative for carcinoma.

J. MARGINAL PALATE:

Squamous mucosa, submucosa, salivary gland, negative for carcinoma.

K. ALVEOLAR RIDGE INFERIOR:

Squamous mucosa, submucosa and skeletal muscle, negative for carcinoma.

L. ORAL PHARYNGEAL MARGIN:

Squamous mucosa, submucosa and skeletal muscle, negative for carcinoma.

M. PERINEURIUM:

Fibroadipose tissue, negative for carcinoma.

N. DEEP SUPERIOR ALVEOLAR RIDGE:

Fibroadipose tissue, negative for carcinoma.

O. SUPERIOR ALVEOLAR RIDGE:

Fibroadipose tissue, negative for carcinoma.

P. COMPOSITE RESECTION RIGHT RETROMOLAR TRIGONE:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 4 of 12]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

SPINDLE CELL SQUAMOUS CELL CARCINOMA in right retromolar trigone, 2.5 cm.

There is extensive ulceration.

The tumor extends to 0.2 cm from deep margin.

The superior, inferior, lateral and medial margins are negative for carcinoma.

There is perineural invasion, and no definitive lymphovascular invasion.

Q. PERIOSTEUM MEDIAL MANDIBLE:

Fibroadipose tissue, negative for carcinoma.

R. LEVEL 1 SENTINEL NODE RIGHT PERIFACIAL ANTERIOR:

METASTATIC SPINDLE SQUAMOUS CELL CARCINOMA, to one out of one (1/1) lymph nodes.
Largest focus is 1.0 cm. Extranodal extension is present.

S. SENTINEL NODE #2:

One lymph node, negative for carcinoma.

T. LYMPH NODE JUGULAR VIEW:

One lymph node, negative for carcinoma.

U. LEVEL 2 SENTINEL NODE:

METASTATIC SPINDLE CELL SQUAMOUS CELL CARCINOMA to one out of one (1/1) lymph nodes.
Largest focus is 0.2 cm.

V. SECOND LEVEL 2 SENTINEL NODE:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 5 of 12]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

METASTATIC SPINDLE CELL SQUAMOUS CELL CARCINOMA to one out of one (1/1) lymph nodes.
Largest focus is 0.2 cm. Extranodal extension is present.

W. PTERYGOID MUSCLE MARGIN POSTERIOR:

Skeletal muscle, negative for carcinoma.

X. PTERYGOID MUSCLE MARGIN ANTERIOR:

Skeletal muscle and fibrous tissue; negative for carcinoma.

Y. TOOTH #31:

Tooth for gross only.

Z. FINAL MARGIN AT MAXILLA:

Squamous mucosa, submucosa and bone; negative for carcinoma.

AA. FINAL BONE INFERIOR:

Bone, skeletal muscle, and fibroadipose tissue, negative for carcinoma.

BB. FINAL MARGIN AT MANDIBLE:

Bone, negative for carcinoma.

CC. MARGINAL SECTIONAL MANDIBULECTOMY:

Bone with extensive reactive changes and bone remodeling.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 6 of 12]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

DD. TISSUE ABOVE MANDIBULAR MARGIN:

Salivary gland, negative for carcinoma.

EE. LYMPH NODE ADJACENT TO TAIL OF PAROTID:

Salivary gland, one lymph node, negative for carcinoma.

Fibroadipose tissue, negative for carcinoma.

FF. RIGHT NECK LEVEL 2A:

Two lymph nodes, negative for carcinoma.

GG. LEVEL 5 NODE:

One lymph node, negative for carcinoma.

HH. RIGHT NECK LEVELS 1B, 2A, 3, 4:

Salivary gland, negative for carcinoma.

Twenty six lymph nodes, negative for carcinoma (0/26).

II. RIGHT NECK LEVEL 2B:

Four lymph nodes, negative for carcinoma (0/4).

AJCC: pT2, N2b, MX

See tumor summary.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 7 of 12]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

NOTE: Immunohistochemistry results to follow.

Surgical Pathology Cancer Case Summary:

PHARYNX (OROPHARYNX, HYPOPHARYNX, NASOPHARYNX): Incisional Biopsy, Excisional Biopsy, Resection

Specimen: Oropharynx

Received: Fresh

Procedure: Resection

Other: Mandible and retromolar trigone

Specimen Integrity: Fragmented

Specimen Size:

Greatest dimension: 4.0 x 3.5 x 1.5 cm

Specimen Laterality: Right

Tumor Site: Oropharynx

Other: Retromolar trigone

Tumor Laterality: Right

Tumor Focality: Single focus

Tumor Size:

Greatest dimension: 2.5 cm

Additional dimensions: 1.5 x 1.3 cm

Tumor Description: Ulcerated

Histologic Type:

Variants of Squamous Cell Carcinoma: Spindle cell squamous carcinoma

Margins: Uninvolved by invasive carcinoma

Distance from closest margin: 1 mm

Perineural Invasion: Present

Lymph Nodes, Extranodal Extension: Present

Pathologic Staging:

Primary Tumor: pT2

Regional Lymph Nodes: pN2b

Number of Lymph Nodes Examined: 38

Number of Lymph Nodes Involved: 3

Distant Metastasis: Not applicable

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 8 of 12]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

CLINICAL HISTORY-

PRE-OP DX: Not provided

PROCEDURE: Not provided

RELEVANT CLINICAL HX: Not provided

GROSS DESCRIPTION:

- A. Received fresh and labeled "Tissue medial to mandible" is a gray-tan, irregular-shaped soft tissue fragment, 1.0 x 1.0 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- B. Received fresh and labeled "Tissue tooth socket" is a light-tan, irregular-shaped soft tissue fragment, 0.5 x 0.4 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- C. Received fresh and labeled "Masseter muscle inferior" is a red-brown soft tissue fragment, 1.0 x 0.3 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- D. Received fresh and labeled "Masseter superior, clip inferior" is a red-brown, irregular-shaped soft tissue fragment, 1.3 x 1.0 x 0.3 cm. The clip area is inked black. Submitted in toto in one cassette.
- E. Received fresh and labeled "Tissue over lateral mandible, anterior" are two red-brown and irregular-shaped soft tissue fragments, 1.0 x 1.0 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- F. Received fresh and labeled "Tissue over lateral mandible, posterior" is a red-brown, irregular-shaped soft tissue fragment, 0.8 x 0.7 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- G. Received fresh and labeled "Final bone margin anterior" is a light-tan, irregular-shaped soft tissue fragment, 0.8 x 0.2 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- H. Received fresh and labeled "Buccal mucosa" are multiple gray-tan, irregular-shaped soft tissue fragments, 1.3 x 1.0 x 0.2 cm. Submitted in toto in one cassette for frozen section.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 9 of 12]
(Continued)

GROSS DESCRIPTION: (Continued)

- I. Received fresh and labeled "Floor of mouth muscle, clip anterior" is a light-tan, irregular-shaped soft tissue fragment, 2.0 x 0.2 x 0.2 cm. The clip area is inked black. Submitted in toto in one cassette for frozen section.
- J. Received fresh and labeled "Marginal palate, clip anterior" is a light-tan irregular-shaped soft tissue fragment, 1.5 x 1.0 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- K. Received fresh and labeled "Alveolar ridge inferior" is a light-tan, irregular-shaped soft tissue fragment, 1.0 x 0.3 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- L. Received fresh and labeled "Oral pharyngeal margin, clip inferior" is a light-tan, irregular-shaped soft tissue fragment, 2.5 x 0.2 x 0.2 cm. The clip area is inked black. Submitted in toto in one cassette for frozen section.
- M. Received fresh and labeled "Perineurium" is a light-tan, irregular-shaped soft tissue fragment, 0.6 x 0.4 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- N. Received fresh and labeled "Deep superior alveolar ridge" is a light-tan, irregular-shaped soft tissue fragment, 0.5 x 0.5 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- O. Received fresh and labeled "Superior alveolar ridge" is a light-tan, irregular-shaped soft tissue fragment, 0.3 x 0.2 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- P. Received fresh and labeled "Composite resection right retromolar trigone" is a light-tan, irregular-shaped soft tissue fragment, 4.0 x 3.5 x 1.5 cm. The specimen is oriented with a stitch at superior. The specimen is inked as follows: superior margin inked blue, inferior margin inked green, lateral margin inked orange, medial margin inked red and deep margin inked black. There is a dark-brown, well-circumscribed tumor, 2.5 x 1.5 x 1.3 cm. This tumor is less than 0.1 cm from the deep resection margin (nearest), 0.2 cm from the superior resection margin, 0.5 cm from the lateral resection margin and 1.0 cm from the medial resection margin, 1.8 cm from the inferior resection margin. The specimen is submitted in eight cassettes, as follows:
- | | |
|--------------|---------------------------------------|
| Cassette #1: | Perpendicular section superior margin |
| Cassette #2: | Perpendicular section inferior margin |
| Cassette #3: | Perpendicular section lateral margin |

This report is privileged, confidential and exempt from disclosure under applicable law. If you receive this report inadvertently, please call [REDACTED] and return the report to us by mail.

[page 10 of 12]
(Continued)

GROSS DESCRIPTION: (Continued)

Cassette #4: Perpendicular section medial margin
Cassettes #5-8: Full composite section of tumor

- Q. Received in formalin and labeled "Periosteum medial mandible" is a light-tan, irregular-shaped soft tissue fragment, 0.3 x 0.2 x 0.1 cm. Submitted in toto in one cassette.
- R. Received fresh and labeled "Level I sentinel node, right perifacial anterior" is a gray-tan, ovoid-shaped lymph node, 2.0 x 1.5 x 1.3 cm. The specimen is bisected and submitted in toto in two cassettes for frozen section.
- S. Received fresh and labeled "Sentinel node #2 posterior" is one lymph node, 1.5 x 1.0 x 1.0 cm. The specimen is bisected and submitted in toto in two cassettes.
- T. Received in formalin and labeled "Lymph node jugular vein" is a gray-tan, ovoid-shaped soft tissue fragment, 0.8 x 0.8 x 0.6 cm. The specimen is bisected and submitted in toto in one cassette.
- U. Received in formalin and labeled "Level II sentinel node" is a gray-tan ovoid-shaped lymph node, 2.3 x 1.0 x 1.0 cm. The specimen is bisected and submitted in toto in two cassettes.
- V. Received fresh and labeled "Second level II sentinel node" is a light-tan, ovoid-shaped soft tissue fragment, 2.0 x 1.0 x 0.8 cm. The specimen is bisected and submitted in toto in two cassettes.
- W. Received in formalin and labeled "Pterygoid muscle margin, posterior" is a dark-brown, irregular-shaped soft tissue fragment, 1.5 x 1.0 x 0.5 cm. Submitted in toto in one cassette.
- X. Received in formalin and labeled "Pterygoid muscle margin, anterior" are two dark-brown and irregular-shaped soft tissue fragments, 1.5 x 1.0 x 0.4 cm in aggregate. Submitted in toto in one cassette.
- Y. Received in formalin and labeled "Tooth #31" is a tooth, 2.0 x 1.0 x 0.8 cm. The specimen has a cavity filled with metallic material. No tissue is attached. Submitted for gross description only.
- Z. Received in formalin and labeled "Final margin at axilla" are multiple gray-tan, irregular-shaped soft tissue and bone fragments, 2.0 x 1.0 x 0.5 cm. Submitted in toto in one cassette after decalcification.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 11 of 12]
(Continued)

GROSS DESCRIPTION: (Continued)

- AA. Received in formalin and labeled "Final bone inferior" are two light-tan, irregular-shaped bone fragments, 0.6 x 0.5 x 0.3 cm. Submitted in toto in one cassette after decalcification.
- BB. Received in formalin and labeled "Margin at mandible" are multiple tiny tissue fragments, 0.1 cm each. Submitted in toto in one cassette after decalcification.
- CC. Received in formalin and labeled "Marginal sectional mandibulectomy" is a segment of mandibulectomy, 3.0 x 2.0 x 0.8 cm. There is a dark-brown, well-circumscribed, erosive lesion, 2.0 x 1.0 x 0.5 cm. This lesion is less than 0.1 cm from the resection margin and is inked black. The lesion is 0.9 cm from the opposite two tips and resection margin. The specimen is not oriented. The deep resection margin is inked yellow and the opposite nearest to lesion is inked red. The specimen is submitted in four cassettes as follows:

Cassette #1:	Resection margin closest to tumor en face
Cassette #2:	Resection margin opposite to closest tumor to margin
Cassettes #3&4:	Full section of the lesion after decalcification

- DD. Received in formalin and labeled "Tissue above mandibular margin" is an irregular-shaped, light-tan soft tissue fragment, 0.8 x 0.6 x 0.4 cm in aggregate. Submitted in toto in one cassette.
- EE. Received in formalin and labeled "Lymph node adjacent to tail of parotid" is an irregular-shaped, yellow-tan soft tissue fragment, 2.5 x 1.0 x 0.6 cm. Sections reveal one possible lymph node, 0.4 x 0.3 x 0.3 cm. Submitted in toto in three cassettes as follows:
- | | |
|-----------------|---------------------------|
| Cassette #1: | One possible lymph node |
| Cassettes #2&3: | Remainder of the specimen |
- FF. Received in formalin and labeled "Right neck level IA" is a yellow-tan, irregular-shaped soft tissue fragment, 4.0 x 2.5 x 1.0 cm. Sections reveal two lymph nodes, 0.6 x 0.5 x 0.5 cm and 0.5 x 0.4 x 0.4 cm. Submitted in toto in one cassette.
- GG. Received in formalin and labeled "Level V node" is a dark-brown, ovoid-shaped lymph node, 0.9 x 0.6 x 0.6 cm. The specimen is bisected and submitted in toto in one cassette.
- HH. Received in formalin and labeled "Right neck level IB, IIA, III and IV" is a

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 12 of 12]
(Continued)

GROSS DESCRIPTION: (Continued)

yellow-gray, irregular-shaped soft tissue fragment, 8.0 x 3.0 x 2.5 cm. Sections reveal 26 lymph nodes, ranging from 1.0 cm to 0.2 cm in maximum diameter. Also there is a homogeneous, gray-tan salivary gland, 3.5 x 3.0 x 2.5 cm. Sections reveal homogeneous, gray-tan, grossly unremarkable cut surface. The specimen is submitted in seven cassettes as follows:

Cassette #1: Salivary gland
Cassettes #2-6: Four lymph nodes per cassette
Cassette #7: Six lymph nodes

II. Received in formalin and labeled "Right neck level IIB" is a gray-tan, irregular-shaped fibrofatty tissue fragment, 2.0 x 1.5 x 1.0 cm. Sections reveal four possible lymph nodes, ranging from 0.5 cm to 0.2 cm in greatest dimension. Submitted in toto in one cassette.

OPERATING ROOM CONSULT (FS-CYT)

- A. TISSUE MEDIAL TO MANDIBLE, FS: Skeletal muscle; no tumor present.
B. TISSUE, TOOTH SOCKET, FS: Bone and fibrous tissue; no tumor present.

ATTENDING PATHOLOGIST:

Signed (Signature on file)

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [redacted] and
return the report to us by mail.

Source: NCI Genomic Data Commons file c26a7e3b-79cf-468e-8375-5d63b9c9dfa8 (TCGA-IQ-A61O.487F8B9D-D7BE-441D-BC73-551372A3E558.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).